Somatic mutation profile of tumor specimen TCGA-D3-A51F-06A (aliquot TCGA-D3-A51F-06A-11D-A25O-08) from TCGA case TCGA-D3-A51F, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.5 years (18,806 days).
Specimen TCGA-D3-A51F-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 909afd46-67f7-4fd4-8e27-84769f698e7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51F-10A (Blood Derived Normal), aliquot TCGA-D3-A51F-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da0060a8-3c74-4f8f-9b08-1c1a5761ef44

The open-access MAF lists 108 somatic variants for this specimen: 77 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 29, Nonsense Mutation 5, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ADAMTS19 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.105); catalogued as COSV50768247, COSV99181128; called by muse, mutect2
- ADAMTS19 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.844); catalogued as COSV99181139; called by muse, mutect2
- ADAMTS9 | c.865T>A p.L289I | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as COSV55786791; called by muse, mutect2
- AL645922.1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); catalogued as rs1418127711, COSV54961843; called by muse, mutect2
- APBA1 | c.2477G>A p.R826K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV55233287; called by muse, mutect2
- ARHGAP30 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as rs1225753512, COSV63518203; called by muse, mutect2
- ARMC3 | c.2518G>A p.G840S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as COSV99958894; called by muse, mutect2
- ATP2B4 | c.3466C>T p.P1156S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.02); catalogued as COSV58181775; called by muse, mutect2
- BCAS3 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66778773; called by muse, mutect2
- CBLL2 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV60369779; called by muse, mutect2, varscan2
- CD53 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54762425; called by muse, mutect2
- COL4A6 | c.242T>C p.F81S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57873155; called by muse, mutect2, varscan2
- CTPS2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV63723555; called by muse, mutect2, varscan2
- CTSE | c.740C>T p.S247F (on ENST00000360218; = p.S242F on NM_001910.4) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63061506; called by muse, mutect2
- DSC3 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as COSV64574351; called by muse, mutect2
- DUSP18 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV58181330; called by muse, mutect2, varscan2
- F5 | c.5176C>T p.R1726W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202197877, CM095187, COSV63123847; called by muse, mutect2
- F5 | c.5174G>T p.C1725F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63126291; called by muse, mutect2
- FAM135B | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV50533689; called by muse, mutect2
- GABRQ | c.965T>A p.I322N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV64783322; called by muse, mutect2, varscan2
- GATA4 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1188397343, COSV58734936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFUS | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV71254349; called by muse, mutect2, varscan2
- GLIS3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs757118860, COSV67940990; called by mutect2, varscan2
- HCN3 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV61361965; called by muse, mutect2, varscan2
- HDAC4 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61858304; called by muse, mutect2
- IGKV1-9 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.255); catalogued as rs1334109064; called by muse, mutect2
- ILVBL | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54621366; called by muse, mutect2, varscan2
- INTS2 | c.3175C>T p.Q1059* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV52155282; called by muse, mutect2
- ITGB4 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.217); catalogued as COSV52330187; called by muse, mutect2
- ITGBL1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.123); catalogued as COSV66025423; called by muse, mutect2
- KIR3DL1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV58487257, COSV58488353; called by muse, mutect2
- KPNA2 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV57858446; called by muse, mutect2
- KRT83 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53341391; called by muse, mutect2
- LMNB2 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV57589840; called by muse, mutect2
- MAMDC2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65859680; called by muse, mutect2, varscan2
- MANBA | c.2708C>T p.P903L (on ENST00000642252; = p.P857L on NM_005908.4) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56968606; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3713C>T p.A1238V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363737176, COSV51602083; called by muse, mutect2, varscan2
- MARCHF4 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56107039; called by muse, mutect2
- MCM3AP | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs745866447, COSV52443497; called by mutect2, varscan2
- MUC17 | c.6643C>T p.P2215S | Missense Mutation (SNP) | VAF 33/358 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs539881448, COSV60297526; called by muse, mutect2
- MUC17 | c.12595T>G p.F4199V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60288168, COSV60297535; called by muse, mutect2
- MUC17 | c.12597C>A p.F4199L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100075087, COSV60294303; called by muse, mutect2
- MYO16 | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100697362; called by muse, mutect2
- MYO16 | c.4043C>T p.P1348L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100697363; called by muse, mutect2
- OR2AE1 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60390268; called by muse, mutect2
- OR6K6 | c.172C>T p.P58S (on ENST00000368144; = p.P34S on NM_001005184.1) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV63743775; called by muse, mutect2
- PCDH18 | c.3024G>A p.M1008I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as COSV61270682; called by muse, mutect2, varscan2
- PCDHGA12 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52760881; called by muse, mutect2
- PIK3R3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV53109879; called by muse, mutect2
- PIP5K1C | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs1377666751, COSV58954569; called by muse, mutect2, varscan2
- PLAG1 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57613717; called by muse, mutect2
- PLEKHH1 | c.3215C>T p.A1072V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV61286177; called by muse, mutect2
- PRDM1 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.078); catalogued as rs528735730, COSV64846221, COSV64846932; called by muse, mutect2
- PTPRF | c.3234G>A p.M1078I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV63447235, COSV63448088; called by muse, mutect2, varscan2
- RAB22A | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs1016771532, COSV54832860; called by muse, mutect2
- RAD51AP2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV67588651; called by muse, mutect2
- RBBP8NL | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV53350161; called by muse, mutect2, varscan2
- REXO1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV50084814; called by muse, mutect2
- RIMBP2 | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55474168, COSV55479741; called by muse, mutect2
- RORC | c.1130T>A p.F377Y | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as COSV59094610; called by muse, mutect2
- SCN10A | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV71862322; called by muse, mutect2
- SGCZ | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV66031074; called by muse, mutect2, varscan2
- SKAP1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61148027; called by muse, mutect2
- SLC9A5 | c.2399G>A p.S800N | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.954); catalogued as COSV55363790; called by muse, mutect2
- SLC9C2 | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876685, COSV62947712; called by muse, mutect2
- SLITRK3 | c.2476C>A p.Q826K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.857); catalogued as COSV53851386; called by muse, mutect2
- SPANXN5 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as COSV64968817; called by muse, mutect2
- SPEF2 | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV61550788; called by muse, mutect2, varscan2
- SULT1C4 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV55598504; called by muse, mutect2, varscan2
- SYNE2 | c.3775C>T p.Q1259* | Nonsense Mutation (SNP) | VAF 4/67 reads (6%) | catalogued as COSV59961679; called by muse, mutect2
- USP7 | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.518); catalogued as rs1470748385, COSV61216388; called by muse, mutect2
- ZNF304 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56583828; called by muse, mutect2
- ZNF831 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as COSV64043293; called by muse, mutect2
- CNGA3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- IGHV3-64 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); called by muse, mutect2
- PAAF1 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.678); called by muse, mutect2
- ADAMTS10 | c.1230G>A p.G410= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs782137080, COSV54357325; called by muse, mutect2
- AMER2 | c.1581C>T p.S527= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV63439170; called by muse, mutect2
- ARMC3 | c.2517G>A p.G839= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99958892; called by muse, mutect2
- COL21A1 | c.2268G>A p.V756= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV55162628; called by muse, mutect2, varscan2
- COMP | c.1953G>A p.R651= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV55875901; called by muse, mutect2, varscan2
- CWF19L1 | c.1497C>T p.I499= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV62499610; called by muse, mutect2
- DNM3 | c.864C>T p.H288= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV62463341; called by muse, mutect2
- EEF2K | c.753C>T p.I251= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV53785132; called by muse, mutect2
- GDF3 | c.547C>T p.L183= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV61713282; called by muse, mutect2
- IGSF22 | c.21G>A p.R7= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV100080425; called by muse, mutect2
- ITIH1 | c.2682G>A p.G894= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV56257246; called by muse, mutect2
- KMT2B | c.5217C>T p.S1739= | Silent (SNP) | VAF 21/299 reads (7%) | catalogued as COSV55865969; called by muse, mutect2
- LRP1 | c.6681C>T p.F2227= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs199656095, COSV54520010; called by muse, mutect2, varscan2
- MYH1 | c.261G>A p.K87= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV55444270; called by muse, mutect2
- NALCN | c.4869G>A p.T1623= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs765186169, COSV51953080; called by muse, mutect2, varscan2
- PCDHA3 | c.1485G>A p.V495= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as COSV63544439; called by muse, mutect2
- PDE8A | c.1725G>A p.E575= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs1164015369, COSV59639299; called by muse, mutect2
- PRAME | c.1518C>T p.F506= | Silent (SNP) | VAF 11/167 reads (7%) | catalogued as COSV67162215; called by muse, mutect2
- PTK2B | c.1011C>T p.S337= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV57759190; called by muse, mutect2
- RAI2 | c.1452G>A p.G484= | Silent (SNP) | VAF 19/195 reads (10%) | catalogued as COSV58964796; called by muse, mutect2, varscan2
- S1PR1 | c.798C>T p.I266= | Silent (SNP) | VAF 13/160 reads (8%) | catalogued as rs749589544, COSV59513923; called by muse, mutect2
- SCN1B | c.327C>T p.T109= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV52894813; called by muse, mutect2
- SEZ6L | c.2019G>A p.L673= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV50674256; called by muse, mutect2
- SPANXN3 | c.117G>A p.Q39= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV65140553; called by muse, mutect2
- SPSB3 | c.696C>T p.T232= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs766252919, COSV51602093; called by mutect2, varscan2
- TMEM132D | c.2817G>A p.V939= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV67161585; called by muse, mutect2
- TTBK1 | c.1170C>T p.P390= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV52494609; called by muse, mutect2
- USP6 | c.1332T>C p.G444= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV51490957; called by muse, mutect2, varscan2
- WDR17 | c.3834G>A p.T1278= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs145267415; called by muse, mutect2
- SNORD115-25 | n.55C>T | RNA (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- ZNF271P | n.1375C>T | RNA (SNP) | VAF 3/45 reads (7%) | catalogued as rs923342871; called by muse, mutect2
